Somatic mutation profile of tumor specimen TCGA-5C-A9VG-01A (aliquot TCGA-5C-A9VG-01A-11D-A36X-10) from TCGA case TCGA-5C-A9VG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 58.2 years (21,273 days).
Specimen TCGA-5C-A9VG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) beec0d58-4847-4132-8350-5e5cada1ea5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5C-A9VG-10A (Blood Derived Normal), aliquot TCGA-5C-A9VG-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e3c54fa-932e-4659-85b9-e0f738e485b6

The open-access MAF lists 161 somatic variants for this specimen: 112 protein-altering or splice-affecting, 47 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 47, Frame Shift Del 5, Nonsense Mutation 5, Splice Site 4, In Frame Del 3, Frame Shift Ins 2, Splice Region 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 29/133 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CWF19L1 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 17/99 reads (17%) | catalogued as rs150239404; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 33/113 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABHD17C | c.986C>G p.S329C | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV51917361, COSV99358454; called by muse, mutect2, varscan2
- ABTB2 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs754239852, COSV100130390; called by muse, mutect2, varscan2
- ACHE | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 21/156 reads (13%) | catalogued as COSV99573623; called by muse, mutect2, varscan2
- AMMECR1 | c.218C>G p.P73R | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.052); catalogued as rs778887966, COSV99466092; called by muse, mutect2, varscan2
- ANKRD50 | c.435C>G p.D145E | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101538854; called by muse, mutect2, varscan2
- ARFGEF2 | c.1996C>T p.Q666* | Nonsense Mutation (SNP) | VAF 29/186 reads (16%) | catalogued as rs1325223579, COSV100903914; called by muse, mutect2, varscan2
- ARID3B | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 23/263 reads (9%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.968); catalogued as COSV100654487, COSV60558409; called by muse, mutect2
- ARPC3 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs749007300, COSV99959436; called by muse, mutect2, varscan2
- BSG | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs376649749, COSV100344387; called by muse, mutect2, varscan2
- C11orf24 | c.1244C>G p.T415R | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100422442; called by muse, mutect2, varscan2
- CACNA1A | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 48/237 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.978); catalogued as COSV100800177; called by muse, mutect2, varscan2
- CACTIN | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs746280342, COSV99698130; called by muse, mutect2, varscan2
- CCDC60 | c.1031T>C p.L344P | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.134); catalogued as COSV100554423; called by muse, mutect2, varscan2
- CCNB1 | c.855G>A p.M285I | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV99841171; called by muse, mutect2, varscan2
- CCR3 | c.931T>A p.Y311N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV100656230; called by muse, mutect2, varscan2
- CDA | c.271A>G p.M91V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV66751318; called by muse, mutect2, varscan2
- CDH9 | c.1053C>A p.N351K | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99141128; called by muse, mutect2, varscan2
- CDH9 | c.1052A>C p.N351T | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50521272; called by muse, mutect2, varscan2
- CHRNB1 | c.1365+1G>C p.X455_splice | Splice Site (SNP) | VAF 10/120 reads (8%) | catalogued as COSV100043350; called by muse, mutect2
- CKS1B | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100460308; called by muse, mutect2, varscan2
- CPS1 | c.3782C>T p.S1261F | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99241273; called by muse, mutect2, varscan2
- CUBN | c.8521A>G p.K2841E | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.129); catalogued as rs750965233, COSV100911790; called by muse, mutect2, varscan2
- CYP2D6 | c.1420C>T p.R474W | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs185772085, COSV100637218; called by muse, mutect2, varscan2
- DIO3 | c.794A>C p.Q265P | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100831995; called by muse, mutect2, varscan2
- DNAH17 | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as COSV101101010; called by muse, mutect2, varscan2
- EP300 | c.1046A>G p.H349R | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99606957; called by muse, mutect2, varscan2
- ETS2 | c.274A>C p.K92Q | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV100711134; called by muse, mutect2, varscan2
- FEM1A | c.1199A>G p.Y400C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1449330413, COSV54164824; called by muse, mutect2, varscan2
- FNDC3B | c.256A>C p.I86L | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.155); catalogued as COSV100393297; called by muse, mutect2, varscan2
- GBE1 | c.1336C>T p.L446= | Splice Region (SNP) | VAF 9/81 reads (11%) | catalogued as COSV101450060; called by muse, mutect2, varscan2
- GPR162 | c.535T>G p.F179V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV99163676; called by muse, mutect2, varscan2
- GPR162 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs375616091; called by muse, mutect2, varscan2
- HACD3 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1441683788, COSV99970866; called by muse, mutect2, varscan2
- HLA-B | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs151341351, COSV101317723, COSV69520781; called by muse, mutect2, varscan2
- HTR3B | c.590A>G p.D197G | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV99491618; called by muse, mutect2, varscan2
- IGSF3 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100603985; called by muse, mutect2, varscan2
- ITGB7 | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99913842; called by muse, mutect2, varscan2
- IVL | c.494A>C p.H165P | Missense Mutation (SNP) | VAF 168/374 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100908068, COSV64216049; called by muse, mutect2, varscan2
- IVL | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as rs866828273, COSV100908070; called by muse, mutect2
- KANK3 | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1465876250, COSV100444773; called by muse, mutect2, varscan2
- KCNQ5 | c.737A>G p.D246G | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100570687; called by muse, mutect2
- KIF1C | c.3291G>C p.K1097N | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.497); catalogued as COSV100296891, COSV57903227; called by muse, mutect2, varscan2
- KMT2E | c.1442T>C p.I481T | Missense Mutation (SNP) | VAF 180/515 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV99995587; called by muse, mutect2, varscan2
- KYNU | c.170-1G>C p.X57_splice | Splice Site (SNP) | VAF 41/297 reads (14%) | catalogued as COSV99932607; called by muse, mutect2, varscan2
- L3MBTL4 | c.168G>C p.W56C | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99526639; called by muse, mutect2, varscan2
- LARP1 | c.718C>T p.R240* (on ENST00000518297 / NM_033551.3; = p.R163* on NM_015315.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 11/107 reads (10%) | catalogued as COSV100303265; called by muse, mutect2, varscan2
- LHPP | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as COSV100919172, COSV64331224; called by muse, mutect2, varscan2
- LIPJ | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 49/484 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV100905861; called by muse, mutect2, varscan2
- LZTFL1 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99944702; called by muse, mutect2
- MAEL | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as rs756146420, COSV100901555; called by muse, mutect2
- MEFV | c.1604T>C p.L535S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99560065; called by muse, mutect2, varscan2
- MEIS2 | c.901-1G>A p.X301_splice (on ENST00000561208 / NM_170675.5; = p.X288_splice on NM_002399.3) | Splice Site (SNP) | VAF 13/138 reads (9%) | catalogued as COSV99575522; called by muse, mutect2
- MICALL2 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs375853882; called by muse, mutect2
- MOCS1 | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100418326; called by muse, mutect2, varscan2
- MVP | c.2381A>C p.K794T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs555637285, COSV100651436; called by muse, mutect2, varscan2
- MYF6 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99952614; called by muse, mutect2, varscan2
- MYO5C | c.1655C>A p.A552D | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99953843; called by muse, mutect2, varscan2
- NBEAL2 | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as rs780140037, CD116026, COSV99433891; called by muse, mutect2, varscan2
- NIBAN1 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100836125; called by muse, mutect2, varscan2
- NR1I3 | c.126C>G p.S42R | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.188); catalogued as COSV100915404; called by muse, mutect2
- OR5M10 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs762888666, COSV101595854; called by muse, mutect2, varscan2
- PABPC3 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1290968380, COSV99878832; called by muse, mutect2, varscan2
- PCIF1 | c.1567T>C p.Y523H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59819489; called by muse, mutect2, varscan2
- PKD2 | c.2783G>T p.G928V | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.143); catalogued as COSV99416667; called by muse, mutect2, varscan2
- PLOD2 | c.570T>A p.D190E | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99282195; called by muse, mutect2
- PRKDC | c.8186G>T p.R2729L | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100037775, COSV58051573, COSV58068122; called by muse, mutect2, varscan2
- PRR35 | c.320C>A p.P107H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.094); catalogued as COSV99551685; called by muse, mutect2, varscan2
- PRRC2B | c.5036C>A p.S1679Y | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100260800; called by muse, mutect2, varscan2
- PTPN13 | c.62T>C p.I21T | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV100363808; called by muse, mutect2, varscan2
- PXDNL | c.2228G>A p.G743D | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761678027, COSV100680255; called by muse, mutect2, varscan2
- RBBP6 | c.4654A>G p.K1552E | Missense Mutation (SNP) | VAF 80/474 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.152); catalogued as COSV60505728; called by muse, mutect2, varscan2
- RBL1 | c.846G>C p.K282N | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV100726823; called by muse, mutect2, varscan2
- RBMS3 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs1421332978, COSV56148034; called by muse, mutect2, varscan2
- ROBO4 | c.2396C>T p.A799V | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100127172; called by muse, mutect2, varscan2
- SAFB2 | c.2239C>T p.R747C | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772797669, COSV53044499; called by muse, mutect2, varscan2
- SCEL | c.1837A>T p.R613W (on ENST00000349847 / NM_144777.3; = p.R593W on NM_003843.4) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100582456; called by muse, mutect2, varscan2
- SEMA3E | c.1814G>T p.R605L | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs145707650, COSV100319578, COSV57108396; called by muse, varscan2
- SENP6 | c.3116A>G p.E1039G | Missense Mutation (SNP) | VAF 69/216 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100894242; called by muse, mutect2, varscan2
- SERPINB13 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs1299356314, COSV54027254; called by muse, mutect2, varscan2
- SPTA1 | c.977A>C p.K326T | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.37); catalogued as rs1244079571, COSV100933988; called by muse, mutect2
- TCHH | c.4972G>A p.E1658K | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.711); catalogued as rs749152495, COSV100914833; called by muse, mutect2, varscan2
- TENM4 | c.5353C>G p.H1785D | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99569432; called by muse, mutect2, varscan2
- TNNI3K | c.2210G>A p.S737N | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.968); catalogued as COSV99630792; called by muse, mutect2, varscan2
- TRPA1 | c.3068dup p.L1023Ffs*15 | Frame Shift Ins (INS) | VAF 73/358 reads (20%) | catalogued as rs1181631081; called by mutect2, pindel, varscan2
- TSNARE1 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV100209563; called by muse, mutect2, varscan2
- TXLNB | c.235A>T p.K79* | Nonsense Mutation (SNP) | VAF 43/121 reads (36%) | catalogued as COSV100624761; called by muse, mutect2, varscan2
- UBXN4 | c.82+1G>C p.X28_splice | Splice Site (SNP) | VAF 50/246 reads (20%) | catalogued as COSV99738478; called by muse, mutect2, varscan2
- ULK4 | c.2174A>T p.Q725L | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV100089427; called by muse, mutect2, varscan2
- VCX | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.441); catalogued as rs768350961, COSV58233177; called by muse, mutect2, varscan2
- VCX2 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.368); catalogued as rs771797452; called by muse, mutect2
- VCX3B | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.193); catalogued as rs1291892180; called by mutect2, varscan2
- VPS25 | c.77G>T p.R26L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as COSV99519221; called by muse, mutect2, varscan2
- VWC2 | c.575G>A p.C192Y | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100513647; called by muse, mutect2, varscan2
- WDR33 | c.1366C>A p.Q456K | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as COSV100459397; called by muse, mutect2, varscan2
- ZBED9 | c.1414T>A p.S472T | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as rs376727708; called by muse, mutect2
- ZFHX4 | c.1787G>A p.S596N | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.167); catalogued as rs1402276868, COSV99254207; called by muse, mutect2, varscan2
- ZIC3 | c.580G>T p.G194C | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54973738, COSV54974336; called by muse, mutect2, varscan2
- CBWD3 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ECE1 | c.83_90delinsGTCCT p.E28_D30delinsGP | In Frame Del (DEL) | VAF 18/124 reads (15%) | called by pindel, varscan2*
- EPHB1 | c.1854dup p.V619Cfs*4 | Frame Shift Ins (INS) | VAF 42/131 reads (32%) | called by mutect2, pindel, varscan2
- FAM160A2 | c.1541_1542del p.S514* (on ENST00000449352 / NM_001098794.2; = p.S528* on NM_032127.4) | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by pindel, varscan2
- LRRC24 | c.703_704del p.M235Vfs*40 | Frame Shift Del (DEL) | VAF 20/103 reads (19%) | called by mutect2, pindel, varscan2
- NKIRAS2 | c.204_221del p.A69_H74del | In Frame Del (DEL) | VAF 13/71 reads (18%) | called by mutect2, pindel, varscan2
- NPLOC4 | c.1240_1250del p.E414* | Frame Shift Del (DEL) | VAF 16/134 reads (12%) | called by mutect2, pindel, varscan2
- OR2T3 | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 35/426 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.259); called by muse, mutect2
- PCNX3 | c.2104_2109del p.R702_H703del | In Frame Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel
- PELO | c.1062del p.E354Dfs*6 | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | called by mutect2, pindel, varscan2
- SALL4 | c.515C>G p.A172G | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by mutect2, varscan2
- SALL4 | c.512del p.L171* | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | called by mutect2, pindel, varscan2
- AFM | c.969A>G p.P323= | Silent (SNP) | VAF 89/383 reads (23%) | catalogued as COSV56921090; called by muse, mutect2, varscan2
- AMTN | c.345C>T p.S115= | Silent (SNP) | VAF 47/446 reads (11%) | catalogued as rs201692110, COSV100219623; called by muse, mutect2, varscan2
- ANKRD11 | c.4971G>A p.S1657= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV56365884; called by muse, mutect2, varscan2
- APOH | c.378G>A p.E126= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as rs762382292, COSV99235428; called by muse, mutect2, varscan2
- ARHGEF10 | c.4065G>T p.L1355= (on ENST00000398564; = p.L1330= on NM_014629.4) | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100033341; called by muse, mutect2, varscan2
- ATP8B4 | c.1386C>A p.P462= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as COSV99462766; called by muse, mutect2, varscan2
- AZI2 | c.51C>T p.A17= | Silent (SNP) | VAF 41/183 reads (22%) | catalogued as COSV55425905; called by muse, mutect2, varscan2
- BTBD11 | c.2469G>A p.L823= (on ENST00000280758 / NM_001018072.2; = p.L360= on NM_001017523.2) | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV55030092; called by muse, mutect2, varscan2
- C14orf93 | c.537G>A p.R179= | Silent (SNP) | VAF 25/147 reads (17%) | catalogued as COSV100136554; called by muse, mutect2, varscan2
- CSMD1 | c.5361C>T p.N1787= (on ENST00000520002; = p.N1786= on NM_033225.6) | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs34443453; called by muse, mutect2, varscan2
- DNAAF1 | c.390G>A p.G130= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as COSV100533394; called by muse, mutect2, varscan2
- EDIL3 | c.1320C>T p.D440= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as COSV99673669; called by muse, mutect2, varscan2
- EPHA3 | c.2904C>T p.S968= | Silent (SNP) | VAF 12/310 reads (4%) | catalogued as COSV100341638; called by muse, mutect2
- ESRRB | c.888C>T p.D296= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as rs139812473; called by muse, mutect2, varscan2
- FAT2 | c.8700T>C p.N2900= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as COSV99941266; called by muse, mutect2, varscan2
- FCGBP | c.9270C>T p.F3090= | Silent (SNP) | VAF 15/141 reads (11%) | called by muse, mutect2, varscan2
- IFRD1 | c.654C>T p.I218= | Silent (SNP) | VAF 35/150 reads (23%) | catalogued as COSV99133511; called by muse, mutect2, varscan2
- INA | c.768G>T p.V256= | Silent (SNP) | VAF 26/159 reads (16%) | catalogued as COSV100878541; called by muse, mutect2, varscan2
- KIAA1549 | c.2698C>T p.L900= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as rs1164435882, COSV99649333, COSV99650051; called by muse, mutect2, varscan2
- LIPI | c.1032T>A p.T344= | Silent (SNP) | VAF 19/182 reads (10%) | catalogued as COSV100753256; called by muse, mutect2, varscan2
- LRFN5 | c.336T>G p.T112= | Silent (SNP) | VAF 24/140 reads (17%) | catalogued as COSV99981898; called by muse, mutect2, varscan2
- LRRC7 | c.532C>T p.L178= (on ENST00000651989 / NM_001370785.2; = p.L145= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV99223602; called by muse, mutect2, varscan2
- MAP2 | c.3796A>C p.R1266= | Silent (SNP) | VAF 21/122 reads (17%) | catalogued as COSV99557068; called by muse, mutect2, varscan2
- MEAK7 | c.453T>G p.T151= | Silent (SNP) | VAF 26/142 reads (18%) | catalogued as COSV100640358; called by muse, mutect2, varscan2
- MGA | c.1428C>T p.V476= | Silent (SNP) | VAF 26/145 reads (18%) | catalogued as rs1406866878, COSV99577985; called by muse, mutect2, varscan2
- MON2 | c.870A>G p.R290= | Silent (SNP) | VAF 9/226 reads (4%) | catalogued as COSV99741267; called by muse, mutect2
- MPV17L2 | c.612A>C p.R204= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV99717861; called by muse, mutect2, varscan2
- MTREX | c.1506C>G p.R502= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as COSV100043369; called by muse, mutect2
- MYOF | c.2235A>T p.T745= | Silent (SNP) | VAF 44/141 reads (31%) | catalogued as COSV100824999; called by muse, mutect2, varscan2
- N4BP2 | c.2910G>A p.G970= | Silent (SNP) | VAF 33/142 reads (23%) | catalogued as rs754202067, COSV99788046; called by muse, mutect2, varscan2
- NRN1L | c.351C>A p.A117= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100197372; called by muse, mutect2, varscan2
- NUCB1 | c.19C>A p.R7= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99617588; called by muse, mutect2, varscan2
- NUP155 | c.495G>T p.L165= (on ENST00000231498 / NM_153485.3; = p.L106= on NM_004298.4) | Silent (SNP) | VAF 25/150 reads (17%) | catalogued as COSV99192110; called by muse, mutect2, varscan2
- OR4K15 | c.189G>C p.L63= (on ENST00000305051; = p.L39= on NM_001005486.1) | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs776042991, COSV100520947; called by muse, mutect2, varscan2
- OR51G2 | c.792T>C p.S264= | Silent (SNP) | VAF 35/156 reads (22%) | catalogued as COSV100432000; called by muse, mutect2, varscan2
- PAK1 | c.861A>T p.A287= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV99582793; called by muse, mutect2, varscan2
- PRSS27 | c.330G>A p.V110= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs1269578947, COSV100234430; called by muse, mutect2, varscan2
- PTPRD | c.54G>A p.T18= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs1465139583, COSV100642394; called by muse, mutect2, varscan2
- RNASE12 | c.168G>A p.R56= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as rs768864047, COSV100250418; called by muse, mutect2, varscan2
- RSPO3 | c.81A>T p.G27= | Silent (SNP) | VAF 14/158 reads (9%) | catalogued as COSV100759432; called by muse, mutect2
- RYR3 | c.5175G>T p.V1725= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as COSV101211738; called by muse, mutect2, varscan2
- SEC24C | c.2301T>C p.F767= | Silent (SNP) | VAF 29/131 reads (22%) | catalogued as COSV59541813; called by muse, mutect2, varscan2
- SIN3B | c.402G>C p.G134= | Silent (SNP) | VAF 22/160 reads (14%) | catalogued as COSV99931274; called by muse, mutect2, varscan2
- TMC7 | c.1431C>T p.C477= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as rs769927626, COSV58584709; called by muse, mutect2, varscan2
- TRIM67 | c.996C>T p.H332= | Silent (SNP) | VAF 30/155 reads (19%) | catalogued as rs1383498568, COSV100791990; called by muse, mutect2, varscan2
- VARS1 | c.3393G>T p.R1131= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV100791762; called by muse, mutect2, varscan2
- ZNF274 | c.849T>G p.P283= (on ENST00000610905; = p.P178= on NM_016324.3) | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV100464544; called by muse, mutect2, varscan2
- NXF5 | n.957G>A | RNA (SNP) | VAF 119/419 reads (28%) | catalogued as rs774444304, COSV99533962; called by muse, mutect2, varscan2
- PSG6 | chr19:42902445 A>G | 3'Flank (SNP) | VAF 43/305 reads (14%) | called by muse, mutect2, varscan2
